Surgical pathology report (de-identified scan), TCGA case TCGA-D3-A2JC, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site MD Anderson, specimen TCGA-D3-A2JC-06A (Metastatic).

IHPAA Discrepancy		X

ICD-0-3
Melanoma, NOS 8720/3
Site: lymph node, axillary
C17.3
W 7/24/11

DIAGNOSIS

Patient ID – Sample ID

- A) RIGHT AXILLARY LYMPH NODE LEVEL I-III, EXCISION:
METASTATIC MELANOMA PRESENT IN TWO OF FIFTEEN LYMPH NODES (2/15).
EXTRACAPSULAR EXTENSION IS IDENTIFIED.
LARGEST SIZE IS 60 MM.

Entire report and diagnosis completed by

GROSS DESCRIPTION

(A) RIGHT AXILLARY LYMPH NODE LEVEL I-III, STITCH MARKS HIGHEST LEVEL III - A piece of adipose tissue measuring 13 x 10 x 3.0 cm. The specimen is oriented by long stitch on Level III. The specimen was divided into three levels (1, 2, and 3). Fifteen lymph nodes are identified ranging between 0.7 to 6.0 cm in largest dimension. Tissue bank is taken from one lymph node for research.

SECTION CODE: A1, one lymph node bisected; A2, A3, the largest lymph node serially sectioned, (studies are taken from this lymph node, A1-A3, Level I lymph node); A4, one lymph node bisected; A5, one lymph node; A6, one lymph node bisected; A7, A8, one lymph node serially sectioned (A4-A8, Level II lymph nodes); A9, two lymph nodes; A10, one lymph node bisected; A11, one lymph node bisected; A12, one lymph node bisected; A13, one lymph node bisected; A14, one lymph node bisected; A15, A16 one lymph node serially sectioned; A17, A18, one lymph node serially sectioned.

CLINICAL HISTORY

Melanoma, right axillary metastasis.

SNOMED CODES

"Some tests reported here may have been developed and performance characteristics determined by I specifically cleared or approved by the U.S. Food and Drug Administration."
Released by:

These tests have not been

--END OF REPORT-----

Source: NCI Genomic Data Commons file 549232e6-2aab-4776-b07d-31c8d95c79d3 (TCGA-D3-A2JC.1371FB43-AB0B-439A-837C-4A052D11725D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).